Somatic mutation profile of tumor specimen 0DMN2A from CCDI case PBCAEC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.8 years (1,389 days).
Specimen 0DMN2A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6e78b35-cfa5-4160-b24f-e0ef6c409249.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN14 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8908da00-b26d-406e-9901-7cb5f621629f

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRRTM4 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 255/834 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV69140722; called by muse, varscan2
- POLD1 | c.2803G>C p.A935P | Missense Mutation (SNP) | VAF 115/443 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as COSV54532942; called by muse, varscan2
- DYNC1I1 | c.798dup p.V267Cfs*15 | Frame Shift Ins (INS) | VAF 115/456 reads (25%) | called by pindel, varscan2
